Somatic mutation profile of tumor specimen SM-JU32Y (aliquot 7316UP-979) from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU32Y: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e238e138-e8b0-48f4-8f44-bce8816991e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105214 (Blood Derived Normal), aliquot 7316UP-613-1105214; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c81a75e-7fed-4ea0-a20e-eb1d79744602

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 2, Nonsense Mutation 1, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 24/378 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2
- BAIAP2 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs943691615; called by muse, mutect2, varscan2
- EDC4 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1214063850; called by muse, mutect2, varscan2
- FLG | c.7407C>G p.S2469R | Missense Mutation (SNP) | VAF 107/752 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as rs771465526; called by muse, mutect2, varscan2
- MUC17 | c.8401C>A p.P2801T | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs753157006, COSV60292298; called by muse, mutect2
- MUC4 | c.3575C>G p.S1192* | Nonsense Mutation (SNP) | VAF 32/342 reads (9%) | catalogued as rs1181202036; called by muse, mutect2, varscan2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 57/490 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2, varscan2
- OTOA | c.1138G>A p.V380I (on ENST00000286149; = p.V366I on NM_144672.4) | Missense Mutation (SNP) | VAF 59/400 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs764772897, COSV53750352; called by muse, mutect2, varscan2
- PIEZO2 | c.4073C>T p.T1358M | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777349822, COSV100123409; ClinVar: uncertain significance; called by muse, mutect2
- POU5F1B | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.287); catalogued as COSV101197017; called by muse, mutect2, varscan2
- SHROOM3 | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 57/435 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV56026958; called by muse, mutect2, varscan2
- SUFU | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64015566; called by muse, mutect2, varscan2
- SVEP1 | c.7535C>T p.T2512M | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs200375910; called by muse, mutect2, varscan2
- TMEM200A | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1032893688, COSV51661039; called by muse, mutect2, varscan2
- TRPV5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs775179978, COSV54688182; called by muse, mutect2, varscan2
- VIT | c.1495G>A p.V499I (on ENST00000389975 / NM_001177969.1; = p.V514I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs773111980, COSV64899202; called by muse, mutect2, varscan2
- ZFP64 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs371444820, COSV53803673; called by muse, mutect2
- ANKRD40 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CCDC50 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDK17 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- CRTC3 | c.512dup p.S172Efs*25 | Frame Shift Ins (INS) | VAF 20/162 reads (12%) | called by mutect2, pindel, varscan2
- DNAH11 | c.8836A>G p.K2946E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- GRID2 | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ITGAL | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- LSR | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRM3 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- RRAGA | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2
- RSPH1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- SLC17A2 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- ZNF676 | c.503C>T p.T168I (on ENST00000650058; = p.T136I on NM_001001411.3) | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2
- CFAP61 | c.693G>A p.V231= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- CRB2 | c.579C>T p.C193= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs758424803; called by muse, mutect2, varscan2
- GOLGA8H | c.567C>A p.A189= | Silent (SNP) | VAF 44/573 reads (8%) | called by muse, mutect2
- GRHL3 | c.1233C>T p.D411= (on ENST00000350501 / NM_198174.3; = p.D416= on NM_021180.3) | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs140971496; called by muse, mutect2, varscan2
- GRM8 | c.1536G>A p.P512= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs774632571, COSV58809093, COSV58817276, COSV58852761; called by muse, varscan2
- MSH2 | c.2400A>G p.L800= | Silent (SNP) | VAF 29/218 reads (13%) | catalogued as rs201298777; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- OR6C6 | c.315G>A p.P105= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs751973071; called by muse, mutect2
- PLEKHG3 | c.1986C>T p.D662= (on ENST00000394691; = p.D718= on NM_001308147.2) | Silent (SNP) | VAF 40/317 reads (13%) | called by muse, mutect2, varscan2
- SPHKAP | c.1986C>T p.V662= | Silent (SNP) | VAF 32/194 reads (16%) | catalogued as rs61752224, COSV60872785; called by muse, mutect2, varscan2
- KLC2 | c.*328C>T | 3'UTR (SNP) | VAF 49/366 reads (13%) | catalogued as rs1224502861; called by muse, mutect2, varscan2
- MTRNR2L9 | n.67C>T | RNA (SNP) | VAF 12/84 reads (14%) | catalogued as rs1180018123; called by muse, mutect2
- NCAM1 | c.2456+1105C>T | Intron (SNP) | VAF 40/294 reads (14%) | called by muse, mutect2, varscan2
- SPINK9 | c.87+30T>C | Intron (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
